Somatic mutation profile of tumor specimen C3L-03123-02 (aliquot CPT0166760007) from CPTAC case C3L-03123, project CPTAC-3 (Pancreas — Ductal and Lobular Neoplasms). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 60.6 years (22,137 days).
Specimen C3L-03123-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 763d24aa-c7f0-47fe-afd0-f60e6f49dc79.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-03123-31 (Blood Derived Normal), aliquot CPT0166790002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4118e184-57d5-4da6-bad1-a66b937fea40

The open-access MAF lists 555 somatic variants for this specimen: 374 protein-altering or splice-affecting, 122 silent, 59 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 340, Silent 122, Intron 28, 3'UTR 14, Nonsense Mutation 12, Splice Site 9, 5'UTR 6, Frame Shift Del 6, RNA 5, 5'Flank 5, Splice Region 4, Nonstop Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.95T>C p.L32P | Missense Mutation (SNP) | VAF 73/503 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs878853650, CM950225, COSV58684533, COSV58685103; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- HLCS | c.1522C>T p.R508W | Missense Mutation (SNP) | VAF 32/664 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs119103229, CM960833, COSV100358162; ClinVar: pathogenic; called by muse, mutect2
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 231/720 reads (32%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.578A>T p.H193L | Missense Mutation (SNP) | VAF 135/745 reads (18%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs786201838, CM083194, CM951225, COSV52662414, COSV52663304, COSV52681707; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- AAGAB | c.503C>T p.A168V | Missense Mutation (SNP) | VAF 30/364 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV99971832; called by muse, mutect2
- ABCA4 | c.4549C>T p.R1517C | Missense Mutation (SNP) | VAF 69/712 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.394); catalogued as rs1800550, CM970012, COSV64676804; called by muse, mutect2
- ABCB1 | c.1984C>G p.L662V | Missense Mutation (SNP) | VAF 46/443 reads (10%) | SIFT tolerated (0.26); PolyPhen benign (0.033); catalogued as COSV99712017; called by muse, mutect2, varscan2
- ABCC5 | c.338C>T p.S113L | Missense Mutation (SNP) | VAF 34/341 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.14); catalogued as rs758646463, COSV55586863; called by muse, mutect2, varscan2
- AGO4 | c.53G>A p.R18H | Missense Mutation (SNP) | VAF 48/312 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs759153717, COSV64617690; called by muse, mutect2, varscan2
- ANKRD40 | c.457G>A p.A153T | Missense Mutation (SNP) | VAF 30/186 reads (16%) | SIFT tolerated (0.51); PolyPhen benign (0.01); catalogued as COSV53334620; called by muse, mutect2, varscan2
- ARHGAP26 | c.1805C>T p.T602M | Missense Mutation (SNP) | VAF 24/150 reads (16%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.893); catalogued as rs770272847, COSV50843457; called by muse, mutect2, varscan2
- ARHGAP4 | c.1534T>C p.F512L | Missense Mutation (SNP) | VAF 30/220 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.767); catalogued as COSV100604020; called by muse, mutect2, varscan2
- ARMC12 | c.563G>A p.R188Q (on ENST00000373866 / NM_001286574.2; = p.R215Q on NM_145028.5) | Missense Mutation (SNP) | VAF 52/581 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.864); catalogued as rs756954794, COSV55362032; called by muse, mutect2
- ARMC5 | c.2570G>A p.R857H | Missense Mutation (SNP) | VAF 24/274 reads (9%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as rs780179674; called by muse, mutect2
- ATN1 | c.2897C>T p.P966L | Missense Mutation (SNP) | VAF 107/640 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.933); catalogued as rs1237045317; called by muse, mutect2, varscan2
- ATR | c.2002C>T p.R668W | Missense Mutation (SNP) | VAF 27/310 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs761352811; called by muse, mutect2
- B4GALNT3 | c.37C>A p.L13M | Missense Mutation (SNP) | VAF 98/448 reads (22%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.445); catalogued as rs1287065902; called by muse, mutect2
- BAHCC1 | c.827G>A p.R276H | Missense Mutation (SNP) | VAF 29/180 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs782588265; called by muse, mutect2, varscan2
- BEND3 | c.1063G>A p.A355T | Missense Mutation (SNP) | VAF 52/494 reads (11%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0); catalogued as rs199991434; called by muse, mutect2
- BICD2 | c.641G>A p.R214H | Missense Mutation (SNP) | VAF 48/350 reads (14%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.999); catalogued as rs373760993; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- C10orf71 | c.3946G>A p.E1316K | Missense Mutation (SNP) | VAF 41/337 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.429); catalogued as rs1438668932, COSV60506011, COSV60506026; called by muse, mutect2, varscan2
- C11orf52 | c.209T>C p.M70T | Missense Mutation (SNP) | VAF 45/748 reads (6%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as rs587644032; called by muse, mutect2
- C1RL | c.419G>A p.R140H | Missense Mutation (SNP) | VAF 42/483 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.048); catalogued as rs201847594, COSV56926292; called by muse, mutect2
- CABIN1 | c.950C>T p.T317M | Missense Mutation (SNP) | VAF 91/1044 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs1056788500, COSV54088980; called by muse, mutect2
- CABIN1 | c.4988C>T p.T1663M | Missense Mutation (SNP) | VAF 73/628 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs552263560; called by muse, mutect2, varscan2
- CACNA1I | c.4956C>A p.C1652* | Nonsense Mutation (SNP) | VAF 38/288 reads (13%) | catalogued as rs758332678; called by muse, mutect2, varscan2
- CAPNS2 | c.523C>T p.R175W | Missense Mutation (SNP) | VAF 34/288 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.556); catalogued as rs981036666; called by muse, mutect2, varscan2
- CARS2 | c.217G>A p.A73T | Missense Mutation (SNP) | VAF 24/148 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.098); catalogued as rs761282112; called by muse, mutect2, varscan2
- CASZ1 | c.1621G>A p.G541S | Missense Mutation (SNP) | VAF 42/427 reads (10%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs376189072; called by muse, mutect2, varscan2
- CCDC103 | c.307G>A p.A103T | Missense Mutation (SNP) | VAF 16/522 reads (3%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.842); catalogued as COSV99493084; called by muse, mutect2
- CCDC184 | c.443C>A p.P148H | Missense Mutation (SNP) | VAF 14/242 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.632); catalogued as COSV100344059; called by muse, mutect2
- CD226 | c.622G>A p.V208I | Missense Mutation (SNP) | VAF 73/674 reads (11%) | SIFT tolerated (0.72); PolyPhen benign (0.003); catalogued as rs143019865; called by muse, mutect2, varscan2
- CDAN1 | c.2174G>A p.R725Q | Missense Mutation (SNP) | VAF 89/908 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs962870388, COSV100661202; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CDKN2A | c.253G>A p.A85T | Missense Mutation (SNP) | VAF 150/1052 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs878853646, CD111993, CD961883, CM960271, COSV58683653, COSV58684450, COSV58705440; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CEP152 | c.3620T>C p.V1207A | Missense Mutation (SNP) | VAF 24/152 reads (16%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.792); catalogued as rs1182095328; called by muse, mutect2, varscan2
- CEP170B | c.2141C>T p.A714V (on ENST00000453495; = p.A643V on NM_015005.3) | Missense Mutation (SNP) | VAF 48/299 reads (16%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as rs1379945932; called by muse, mutect2, varscan2
- CFTR | c.2705G>A p.S902N | Missense Mutation (SNP) | VAF 55/554 reads (10%) | SIFT tolerated (0.29); PolyPhen benign (0.009); catalogued as CD1212249; called by muse, mutect2
- CHD7 | c.5786T>C p.M1929T | Missense Mutation (SNP) | VAF 53/559 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.052); catalogued as rs1363962894; called by muse, mutect2
- CHERP | c.1636C>T p.R546C | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as rs868606588; called by muse, mutect2, varscan2
- CHRM4 | c.358G>A p.V120I | Missense Mutation (SNP) | VAF 24/509 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.241); catalogued as rs1247534212, COSV63127569; called by muse, mutect2
- CLTA | c.730G>A p.A244T (on ENST00000242285 / NM_007096.4; = p.A214T on NM_001833.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 19/148 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.05); catalogued as rs747907818; called by muse, mutect2, varscan2
- COPE | c.412C>T p.R138C | Missense Mutation (SNP) | VAF 46/327 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs781041495; called by muse, mutect2, varscan2
- CORIN | c.889G>A p.D297N | Missense Mutation (SNP) | VAF 50/315 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs751480678, COSV56687485; called by muse, varscan2
- CPA5 | c.662G>A p.R221H | Missense Mutation (SNP) | VAF 21/203 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.005); catalogued as rs530926535, COSV62570788; called by muse, mutect2, varscan2
- CPEB2 | c.464G>C p.C155S | Missense Mutation (SNP) | VAF 24/196 reads (12%) | SIFT deleterious, low confidence (0); catalogued as COSV99470365; called by muse, mutect2, varscan2
- CROCC2 | c.3149G>A p.R1050H | Missense Mutation (SNP) | VAF 74/325 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0.009); catalogued as rs965037522; called by muse, mutect2, varscan2
- CRYBG3 | c.1169G>A p.R390H | Missense Mutation (SNP) | VAF 35/283 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.147); catalogued as rs1409061443, COSV51711661; called by muse, mutect2, varscan2
- CSK | c.1288C>T p.R430W | Missense Mutation (SNP) | VAF 59/566 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54974500; called by muse, mutect2, varscan2
- CXXC1 | c.1867C>T p.R623C | Missense Mutation (SNP) | VAF 18/390 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.964); catalogued as COSV53276489; called by muse, mutect2
- DCTN5 | c.352C>T p.R118C | Missense Mutation (SNP) | VAF 32/218 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.08); catalogued as rs373307086; called by muse, mutect2, varscan2
- DDO | c.929del p.G310Afs*16 (on ENST00000368924 / NM_001368172.1; = p.G251Afs*16 on NM_004032.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 25/234 reads (11%) | catalogued as rs760049563; called by mutect2, pindel, varscan2
- DIDO1 | c.2324C>T p.A775V | Missense Mutation (SNP) | VAF 13/131 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.202); catalogued as rs566821138; called by muse, mutect2
- DNAJC8 | c.610C>T p.R204W | Missense Mutation (SNP) | VAF 49/574 reads (9%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.613); catalogued as rs770285519; called by muse, mutect2
- DNHD1 | c.4558C>T p.R1520W | Missense Mutation (SNP) | VAF 29/454 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as rs1343369713; called by muse, mutect2
- DNMT3L | c.571C>T p.R191W | Missense Mutation (SNP) | VAF 41/353 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs943771422, COSV99533392; called by muse, mutect2, varscan2
- DPYS | c.1492G>A p.A498T | Missense Mutation (SNP) | VAF 71/584 reads (12%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs368932527; called by muse, mutect2, varscan2
- EML6 | c.4712C>T p.T1571M | Missense Mutation (SNP) | VAF 25/200 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs925445892, COSV62864133; called by muse, mutect2
- ERCC2 | c.1132C>T p.R378C | Missense Mutation (SNP) | VAF 34/319 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs186220206; called by muse, mutect2, varscan2
- EZHIP | c.271G>A p.A91T | Missense Mutation (SNP) | VAF 77/740 reads (10%) | SIFT tolerated (0.24); PolyPhen benign (0.105); catalogued as rs781827373; called by muse, mutect2, varscan2
- F12 | c.755C>T p.A252V | Missense Mutation (SNP) | VAF 30/524 reads (6%) | SIFT tolerated (0.87); PolyPhen benign (0.265); catalogued as rs985081288; called by muse, mutect2
- FAM199X | c.1037G>A p.R346H | Missense Mutation (SNP) | VAF 62/678 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.984); catalogued as rs782702516, COSV55433214, COSV55433623; called by muse, mutect2
- FAM71E1 | c.641G>A p.R214Q (on ENST00000600100 / NM_001308429.2; = p.R198Q on NM_138411.3) | Missense Mutation (SNP) | VAF 120/986 reads (12%) | SIFT tolerated (0.3); PolyPhen benign (0.053); catalogued as rs919256556; called by muse, varscan2
- FAM83G | c.1895G>A p.R632H | Missense Mutation (SNP) | VAF 21/146 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as rs374490985; called by muse, mutect2, varscan2
- FANCM | c.4354G>T p.A1452S | Missense Mutation (SNP) | VAF 64/386 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.703); catalogued as COSV57508007; called by muse, mutect2, varscan2
- FAT1 | c.6766G>A p.A2256T | Missense Mutation (SNP) | VAF 35/330 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs752611276, COSV71675024; called by muse, mutect2, varscan2
- FBXL2 | c.1031G>A p.R344Q | Missense Mutation (SNP) | VAF 36/942 reads (4%) | SIFT tolerated (0.92); PolyPhen benign (0); catalogued as rs376352305; called by muse, mutect2
- FDPS | c.448C>T p.R150W | Missense Mutation (SNP) | VAF 49/434 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.108); catalogued as rs1273852227, COSV100756081, COSV63115267; called by muse, mutect2, varscan2
- FLOT2 | c.307G>A p.V103I | Missense Mutation (SNP) | VAF 62/461 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs777162321, COSV67529033; called by muse, mutect2, varscan2
- FN1 | c.4777G>T p.D1593Y | Missense Mutation (SNP) | VAF 40/634 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV60548363; called by muse, mutect2
- FOXP1 | c.721G>A p.A241T | Missense Mutation (SNP) | VAF 28/552 reads (5%) | SIFT tolerated (0.41); PolyPhen benign (0.014); catalogued as rs1287988102, COSV59557975; called by muse, mutect2
- GALNT15 | c.1316G>A p.R439H | Missense Mutation (SNP) | VAF 57/566 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.886); catalogued as rs149803620; called by muse, mutect2, varscan2
- GLI3 | c.3550G>A p.A1184T | Missense Mutation (SNP) | VAF 23/201 reads (11%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs1240989723, COSV67890876; called by muse, mutect2
- GPR153 | c.208C>T p.R70W | Missense Mutation (SNP) | VAF 18/244 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs762655763; called by muse, mutect2
- GPR55 | c.292G>A p.E98K | Missense Mutation (SNP) | VAF 18/424 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs866729102; called by muse, mutect2
- GRAMD4 | c.1138C>T p.P380S | Missense Mutation (SNP) | VAF 62/431 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.521); catalogued as rs1011786250; called by muse, mutect2, varscan2
- GRID1 | c.1583G>A p.S528N | Missense Mutation (SNP) | VAF 21/228 reads (9%) | SIFT tolerated (0.98); PolyPhen benign (0.01); catalogued as COSV60052579; called by muse, mutect2
- H1-7 | c.296C>T p.A99V | Missense Mutation (SNP) | VAF 140/640 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.059); catalogued as rs775913130, COSV100622260; called by muse, mutect2, varscan2
- HAGH | c.529G>A p.A177T | Missense Mutation (SNP) | VAF 21/191 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); catalogued as rs749671466; called by muse, mutect2, varscan2
- HELZ2 | c.4270C>T p.R1424C (on ENST00000467148 / NM_001037335.2; = p.R855C on NM_033405.3) | Missense Mutation (SNP) | VAF 57/499 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs369824033; called by muse, mutect2, varscan2
- HERC2 | c.1691C>T p.A564V | Missense Mutation (SNP) | VAF 60/658 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.985); catalogued as rs367923183; called by muse, mutect2
- IFIT2 | c.955G>A p.A319T | Missense Mutation (SNP) | VAF 48/494 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.075); catalogued as rs775027680, COSV51078970, COSV99260146; called by muse, mutect2
- IFNGR2 | c.340C>T p.R114C | Missense Mutation (SNP) | VAF 124/846 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1243506079, CM004651; called by muse, mutect2, varscan2
- IL7R | c.330G>T p.K110N | Missense Mutation (SNP) | VAF 40/336 reads (12%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.997); catalogued as COSV57414424; called by muse, mutect2, varscan2
- ING5 | c.211G>A p.A71T | Missense Mutation (SNP) | VAF 50/313 reads (16%) | SIFT tolerated (0.44); PolyPhen benign (0.352); catalogued as rs747667282; called by muse, mutect2, varscan2
- INTS10 | c.1325C>T p.T442M | Missense Mutation (SNP) | VAF 44/432 reads (10%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.997); catalogued as rs200006596; called by muse, mutect2
- INTS13 | c.434C>T p.T145I | Missense Mutation (SNP) | VAF 56/660 reads (8%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.575); catalogued as rs1301560274; called by muse, mutect2
- IQCE | c.490G>A p.V164M | Missense Mutation (SNP) | VAF 50/517 reads (10%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs749622221, COSV100383649; called by muse, mutect2
- ISCA1 | c.136-2A>G p.X46_splice | Splice Site (SNP) | VAF 28/402 reads (7%) | catalogued as COSV100276472; called by muse, mutect2
- KCNA1 | c.544G>A p.V182I | Missense Mutation (SNP) | VAF 24/318 reads (8%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as COSV101230141, COSV66838528; called by muse, mutect2
- KCNS3 | c.68dup p.F24Lfs*2 | Frame Shift Ins (INS) | VAF 71/342 reads (21%) | catalogued as rs1167994655; called by mutect2, pindel, varscan2
- KCTD10 | c.583C>T p.R195C | Missense Mutation (SNP) | VAF 64/782 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.886); catalogued as COSV57327587; called by muse, mutect2
- KDM4B | c.2035C>T p.R679C | Missense Mutation (SNP) | VAF 38/326 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.188); catalogued as rs140874022; called by muse, mutect2, varscan2
- KIAA2026 | c.2187del p.A730Qfs*26 | Frame Shift Del (DEL) | VAF 20/124 reads (16%) | catalogued as rs749990720; called by mutect2, varscan2
- KIRREL3 | c.364G>A p.D122N | Missense Mutation (SNP) | VAF 16/236 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs767674597, COSV73104760; called by muse, mutect2
- KLK5 | c.280G>A p.G94R | Missense Mutation (SNP) | VAF 64/603 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs780972904, COSV100307189, COSV60451823; called by muse, mutect2, varscan2
- KLK7 | c.653T>C p.L218P | Missense Mutation (SNP) | VAF 50/522 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1397233076; called by muse, mutect2, varscan2
- KMT2B | c.1181C>T p.A394V | Missense Mutation (SNP) | VAF 14/144 reads (10%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); catalogued as rs1273880068; called by muse, mutect2
- KMT2B | c.6995G>A p.R2332H | Missense Mutation (SNP) | VAF 74/445 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as rs758088530, COSV55856608; called by muse, mutect2, varscan2
- KSR1 | c.1690C>T p.R564W (on ENST00000644974 / NM_001367810.1; = p.R449W on NM_014238.2) | Missense Mutation (SNP) | VAF 124/826 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.019); catalogued as rs879225861, COSV52028283; called by muse, mutect2, varscan2
- LDLRAD4 | c.280C>T p.R94W | Missense Mutation (SNP) | VAF 46/568 reads (8%) | SIFT tolerated (0.16); PolyPhen benign (0.006); catalogued as rs948982534; called by muse, mutect2
- LINGO4 | c.109T>C p.C37R | Missense Mutation (SNP) | VAF 8/160 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1301124394; called by muse, mutect2
- LRBA | c.6175G>A p.D2059N | Missense Mutation (SNP) | VAF 26/308 reads (8%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.916); catalogued as rs1285852025; called by muse, mutect2
- LRRC14B | c.1391G>A p.R464Q | Missense Mutation (SNP) | VAF 132/900 reads (15%) | SIFT tolerated (0.78); PolyPhen benign (0.012); catalogued as rs764290390, COSV57255999, COSV57256442; called by muse, mutect2, varscan2
- LRRC31 | c.127G>A p.D43N | Missense Mutation (SNP) | VAF 34/289 reads (12%) | SIFT tolerated (0.3); PolyPhen benign (0.145); catalogued as rs1257443008; called by muse, mutect2, varscan2
- LRRC8E | c.2165G>A p.R722H | Missense Mutation (SNP) | VAF 37/325 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.005); catalogued as rs190239641; called by muse, mutect2, varscan2
- LRRK1 | c.2509C>T p.R837* | Nonsense Mutation (SNP) | VAF 22/210 reads (10%) | catalogued as rs1366577662; called by muse, mutect2, varscan2
- MAGEB1 | c.977G>A p.R326H | Missense Mutation (SNP) | VAF 42/304 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.27); catalogued as COSV66775656; called by muse, mutect2, varscan2
- MATN4 | c.268G>A p.A90T | Missense Mutation (SNP) | VAF 16/149 reads (11%) | PolyPhen benign (0.053); catalogued as rs1308939445, COSV59212550, COSV59215522; called by muse, mutect2, varscan2
- MDGA1 | c.1574G>A p.R525H | Missense Mutation (SNP) | VAF 25/268 reads (9%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.781); catalogued as COSV51801910; called by muse, mutect2
- MED16 | c.2023G>A p.V675M | Missense Mutation (SNP) | VAF 54/511 reads (11%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.643); catalogued as rs755389475; called by muse, varscan2
- MSANTD3 | c.163G>A p.E55K | Missense Mutation (SNP) | VAF 59/524 reads (11%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.671); catalogued as COSV58492424; called by muse, mutect2, varscan2
- MTOR | c.34G>A p.A12T | Missense Mutation (SNP) | VAF 28/191 reads (15%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); catalogued as rs527289325, COSV63880039; called by muse, mutect2, varscan2
- MUC2 | c.2953G>A p.G985R | Missense Mutation (SNP) | VAF 17/276 reads (6%) | SIFT deleterious, low confidence (0); catalogued as rs1236888159; called by muse, mutect2
- MUC5B | c.13420G>A p.A4474T | Missense Mutation (SNP) | VAF 105/899 reads (12%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0); catalogued as rs753687590; called by muse, mutect2, varscan2
- MYO9B | c.401G>A p.R134H | Missense Mutation (SNP) | VAF 65/473 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.249); catalogued as rs201870397; called by muse, mutect2, varscan2
- NBEA | c.722C>T p.A241V | Missense Mutation (SNP) | VAF 29/259 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1478929230, COSV59791392; called by muse, mutect2, varscan2
- NEB | c.18453G>A p.S6151= | Splice Region (SNP) | VAF 69/307 reads (22%) | catalogued as rs769787871, COSV51083619; called by muse, mutect2, varscan2
- NFATC1 | c.1756G>A p.E586K | Missense Mutation (SNP) | VAF 21/180 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53698316, COSV99501587; called by muse, mutect2, varscan2
- NFIX | c.1420G>A p.A474T (on ENST00000592199 / NM_001365902.3; = p.A424= on NM_002501.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 50/564 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.06); catalogued as rs777228135; called by muse, mutect2
- NFKBIL1 | c.1018C>T p.R340C | Missense Mutation (SNP) | VAF 42/464 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as rs200385924; called by muse, mutect2
- NIPA1 | c.962T>C p.M321T | Missense Mutation (SNP) | VAF 29/427 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as COSV61680728; called by muse, mutect2
- NKX3-1 | c.526C>T p.R176C | Missense Mutation (SNP) | VAF 38/524 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66512049; called by muse, mutect2
- NTRK2 | c.383C>T p.T128M | Missense Mutation (SNP) | VAF 29/333 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as rs201256653, COSV52867961; called by muse, mutect2
- NUBP1 | c.193G>A p.G65S | Missense Mutation (SNP) | VAF 51/405 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.521); catalogued as rs1243561492; called by muse, mutect2, varscan2
- NXPH3 | c.560G>A p.R187Q | Missense Mutation (SNP) | VAF 56/577 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as rs374258057; called by muse, mutect2
- OTUD7A | c.2020G>A p.A674T (on ENST00000307050 / NM_001382637.1; = p.A667T on NM_130901.3) | Missense Mutation (SNP) | VAF 29/267 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.285); catalogued as rs1309256889; called by muse, mutect2, varscan2
- PAPPA2 | c.436G>A p.A146T | Missense Mutation (SNP) | VAF 39/346 reads (11%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs1404998147, COSV100866822; called by muse, mutect2, varscan2
- PCDH1 | c.2495C>T p.T832M | Missense Mutation (SNP) | VAF 54/476 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs555945646; called by muse, mutect2, varscan2
- PCDH12 | c.2785C>T p.R929C | Missense Mutation (SNP) | VAF 61/613 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.65); catalogued as rs182860036, COSV51521112; called by muse, mutect2, varscan2
- PCDHGC5 | c.488G>A p.G163D | Missense Mutation (SNP) | VAF 26/237 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV52776399; called by muse, mutect2, varscan2
- PGPEP1L | c.259G>A p.V87M | Missense Mutation (SNP) | VAF 128/1079 reads (12%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.883); catalogued as rs761032396, COSV100967265; called by muse, mutect2, varscan2
- PHF2 | c.2213C>T p.S738L | Missense Mutation (SNP) | VAF 34/394 reads (9%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs763214520; called by muse, mutect2
- PIP5K1C | c.1654C>T p.R552C | Missense Mutation (SNP) | VAF 57/530 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.794); catalogued as rs367846781, COSV58955071; called by muse, mutect2, varscan2
- PKHD1L1 | c.11522G>A p.R3841Q | Missense Mutation (SNP) | VAF 39/299 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.892); catalogued as rs751619314, COSV65744517; called by muse, mutect2, varscan2
- PLEKHA2 | c.1004G>A p.R335Q | Missense Mutation (SNP) | VAF 77/780 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0.416); catalogued as rs376761444; called by muse, mutect2
- PNPT1 | c.1718A>G p.E573G | Missense Mutation (SNP) | VAF 72/358 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV53177581; called by muse, mutect2, varscan2
- PPM1A | c.1004G>A p.R335H | Missense Mutation (SNP) | VAF 37/188 reads (20%) | SIFT tolerated (0.3); PolyPhen benign (0.005); catalogued as rs755451132, COSV57785310; called by muse, mutect2, varscan2
- PPM1K | c.110C>T p.T37M | Missense Mutation (SNP) | VAF 52/477 reads (11%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.108); catalogued as rs537053098, COSV55796456; called by muse, mutect2, varscan2
- PPP3CA | c.734A>G p.Q245R | Missense Mutation (SNP) | VAF 9/108 reads (8%) | SIFT tolerated (0.52); PolyPhen benign (0.151); catalogued as COSV59928585; called by muse, mutect2
- PRKD2 | c.2615C>T p.A872V | Missense Mutation (SNP) | VAF 35/240 reads (15%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.024); catalogued as rs757479531, COSV52188016; called by muse, mutect2, varscan2
- PRMT7 | c.1592G>A p.R531Q | Missense Mutation (SNP) | VAF 45/300 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as rs753355037; called by muse, mutect2, varscan2
- PRPF40A | c.905C>T p.P302L | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.04); catalogued as rs962275215; called by muse, varscan2
- PRRC2A | c.1880G>A p.R627H | Missense Mutation (SNP) | VAF 32/260 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as rs1011254957; called by muse, mutect2
- PRSS36 | c.2038del p.L680Wfs*6 | Frame Shift Del (DEL) | VAF 36/306 reads (12%) | catalogued as rs771809480; called by mutect2, pindel, varscan2
- PYCR1 | c.947C>T p.A316V | Missense Mutation (SNP) | VAF 71/559 reads (13%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.003); catalogued as rs781071840; called by muse, mutect2, varscan2
- RGS12 | c.1210G>A p.A404T | Missense Mutation (SNP) | VAF 51/493 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.215); catalogued as rs768337709, COSV60907521; called by muse, mutect2, varscan2
- RIC1 | c.254C>T p.T85M | Missense Mutation (SNP) | VAF 15/153 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.656); catalogued as rs747029814; called by muse, mutect2
- RIMS1 | c.2585C>T p.P862L | Missense Mutation (SNP) | VAF 32/386 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.944); catalogued as rs771037675, COSV53462859; called by muse, mutect2
- RNASEH2B | c.361G>A p.V121M | Missense Mutation (SNP) | VAF 62/519 reads (12%) | SIFT tolerated (0.3); PolyPhen benign (0.009); catalogued as rs764980431; called by muse, mutect2, varscan2
- ROBO2 | c.1304C>T p.A435V | Missense Mutation (SNP) | VAF 51/397 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.324); catalogued as rs748723178, COSV59935500; called by muse, mutect2, varscan2
- RPS5 | c.491G>A p.R164Q | Missense Mutation (SNP) | VAF 52/602 reads (9%) | SIFT deleterious (0.05); PolyPhen benign (0.396); catalogued as rs564673381, COSV99545193; called by muse, mutect2
- RUNX1 | c.412G>A p.G138S (on ENST00000344691 / NM_001001890.3; = p.G165S on NM_001754.5) | Missense Mutation (SNP) | VAF 18/592 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs993436723, COSV55867356, COSV55868649, COSV55869928; called by muse, mutect2
- SCART1 | c.445G>A p.E149K | Missense Mutation (SNP) | VAF 90/877 reads (10%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.606); catalogued as rs952448931; called by mutect2, varscan2
- SEMA4A | c.1237G>A p.V413M | Missense Mutation (SNP) | VAF 87/772 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs764520336, COSV61771873; called by muse, mutect2, varscan2
- SERPINI2 | c.176T>C p.V59A | Missense Mutation (SNP) | VAF 37/337 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.396); catalogued as rs1377297396; called by muse, mutect2, varscan2
- SGSM2 | c.2969G>A p.R990Q (on ENST00000426855 / NM_001098509.2; = p.R1035Q on NM_014853.3) | Missense Mutation (SNP) | VAF 46/271 reads (17%) | SIFT tolerated (0.48); PolyPhen benign (0.003); catalogued as rs373345397; called by muse, mutect2, varscan2
- SH2B2 | c.752C>T p.A251V | Missense Mutation (SNP) | VAF 35/356 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.317); catalogued as COSV60825846; called by muse, mutect2, varscan2
- SHTN1 | c.1445G>A p.R482H | Missense Mutation (SNP) | VAF 30/316 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs764643872; called by muse, mutect2
- SKOR2 | c.1084G>A p.V362M | Missense Mutation (SNP) | VAF 12/87 reads (14%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.788); catalogued as rs1197368408; called by muse, mutect2, varscan2
- SLC12A5 | c.2716C>T p.R906C (on ENST00000454036 / NM_001134771.2; = p.R883C on NM_020708.5) | Missense Mutation (SNP) | VAF 12/202 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1161641127, COSV54788554; called by muse, mutect2
- SLC27A3 | c.377C>T p.A126V | Missense Mutation (SNP) | VAF 55/856 reads (6%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.02); catalogued as rs1322019906; called by muse, mutect2
- SLC4A3 | c.1835C>A p.P612H | Missense Mutation (SNP) | VAF 47/1027 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56097579; called by muse, mutect2
- SLC7A2 | c.1592C>T p.A531V (on ENST00000494857 / NM_001370338.1; = p.A570V on NM_003046.6) | Missense Mutation (SNP) | VAF 46/536 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs772998799, COSV50262885; called by muse, mutect2
- SLITRK1 | c.1567C>T p.Q523* | Nonsense Mutation (SNP) | VAF 53/425 reads (12%) | catalogued as COSV65676968; called by muse, mutect2, varscan2
- SMARCAL1 | c.1211C>T p.A404V | Missense Mutation (SNP) | VAF 62/702 reads (9%) | SIFT tolerated (0.33); PolyPhen benign (0.029); catalogued as rs761003078; called by muse, mutect2
- SMOX | c.1505C>T p.P502L | Missense Mutation (SNP) | VAF 14/118 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.076); catalogued as rs1430576325; called by muse, varscan2
- SRRT | c.629G>T p.R210L | Missense Mutation (SNP) | VAF 21/200 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.219); catalogued as rs777364262; called by muse, mutect2
- SV2A | c.1472G>A p.R491H | Missense Mutation (SNP) | VAF 35/332 reads (11%) | SIFT tolerated (0.38); PolyPhen benign (0.001); catalogued as rs199799449; called by muse, mutect2, varscan2
- SYK | c.125G>A p.R42H | Missense Mutation (SNP) | VAF 14/169 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1408106520, COSV65326552, COSV65326829; called by muse, mutect2
- TAOK3 | c.1970G>A p.R657Q | Missense Mutation (SNP) | VAF 87/433 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs753899938, COSV101183383; called by muse, mutect2, varscan2
- TBC1D10C | c.547G>A p.V183M | Missense Mutation (SNP) | VAF 44/302 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs778177831; called by muse, mutect2, varscan2
- TCEANC2 | c.521C>T p.T174M | Missense Mutation (SNP) | VAF 31/283 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.24); catalogued as rs764470272; called by muse, mutect2, varscan2
- TCERG1 | c.2413A>G p.N805D | Missense Mutation (SNP) | VAF 41/254 reads (16%) | SIFT tolerated (0.68); PolyPhen benign (0.003); catalogued as rs755292554; called by muse, mutect2, varscan2
- TDRP | c.511C>T p.R171W | Missense Mutation (SNP) | VAF 23/174 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs773185041, COSV100138523; called by muse, mutect2, varscan2
- TEAD2 | c.883del p.H295Mfs*12 | Frame Shift Del (DEL) | VAF 38/278 reads (14%) | catalogued as rs763321097; called by mutect2, varscan2
- TET1 | c.6113G>A p.R2038H | Missense Mutation (SNP) | VAF 29/465 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65383302; called by muse, mutect2
- TFRC | c.362G>A p.R121H | Missense Mutation (SNP) | VAF 38/307 reads (12%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs772641140, COSV100786409, COSV64053836; called by muse, mutect2, varscan2
- TGFA | c.241C>T p.R81C | Missense Mutation (SNP) | VAF 67/324 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1377948470; called by muse, mutect2, varscan2
- TMC3 | c.2882G>A p.R961H | Missense Mutation (SNP) | VAF 23/225 reads (10%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.001); catalogued as rs779434727, COSV63923699; called by muse, mutect2, varscan2
- TPST2 | c.583C>T p.R195C | Missense Mutation (SNP) | VAF 20/194 reads (10%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.74); catalogued as rs749743940; called by muse, mutect2, varscan2
- TRA2B | c.532C>T p.R178C | Missense Mutation (SNP) | VAF 15/157 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0.098); catalogued as rs1333452193; called by muse, mutect2
- TRAF3IP1 | c.286G>A p.V96M | Missense Mutation (SNP) | VAF 88/366 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs527454385; called by muse, varscan2
- TRIM35 | c.1201C>T p.R401C | Missense Mutation (SNP) | VAF 43/418 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as rs377763568; called by mutect2, varscan2
- TRIM46 | c.154G>A p.V52M | Missense Mutation (SNP) | VAF 40/522 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs907670977; called by muse, mutect2
- TRIM56 | c.1100G>A p.R367Q | Missense Mutation (SNP) | VAF 13/108 reads (12%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as rs763535074, COSV100047822; called by muse, mutect2, varscan2
- TRPC3 | c.1457C>T p.T486M (on ENST00000379645 / NM_001366479.2; = p.T413M on NM_003305.2) | Missense Mutation (SNP) | VAF 64/571 reads (11%) | SIFT tolerated (0.22); PolyPhen benign (0.011); catalogued as rs766044392, COSV99312717; called by muse, mutect2, varscan2
- TTC28 | c.4111G>A p.V1371M | Missense Mutation (SNP) | VAF 28/298 reads (9%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs1364644849; called by muse, mutect2
- TTC29 | c.32G>A p.R11H | Missense Mutation (SNP) | VAF 30/365 reads (8%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as rs759589838, COSV57271312; called by muse, mutect2
- TULP2 | c.875G>A p.R292H | Missense Mutation (SNP) | VAF 58/471 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs768050219; called by muse, mutect2, varscan2
- UMODL1 | c.3690C>T p.I1230= (on ENST00000408910 / NM_001004416.2; = p.I1358= on NM_173568.3) | Splice Region (SNP) | VAF 18/236 reads (8%) | catalogued as rs1021984474; called by muse, mutect2
- USP11 | c.121C>T p.R41W | Missense Mutation (SNP) | VAF 80/756 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV52092520; called by muse, mutect2, varscan2
- USP42 | c.572G>A p.R191H | Missense Mutation (SNP) | VAF 26/280 reads (9%) | SIFT tolerated (0.22); PolyPhen benign (0.152); catalogued as rs763773392, COSV60362082; called by muse, mutect2
- VPS13D | c.3107G>A p.R1036Q | Missense Mutation (SNP) | VAF 46/462 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.065); catalogued as rs145269542; called by muse, mutect2
- VPS50 | c.2330G>A p.R777Q | Missense Mutation (SNP) | VAF 22/206 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs767399519; called by muse, mutect2, varscan2
- WASHC2C | c.1214C>T p.P405L | Missense Mutation (SNP) | VAF 34/538 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs782404473; called by muse, mutect2
- WDR97 | c.4171G>A p.G1391R | Missense Mutation (SNP) | VAF 19/224 reads (8%) | SIFT tolerated, low confidence (0.64); PolyPhen benign (0); catalogued as rs1227698168; called by muse, mutect2
- WRAP73 | c.634C>T p.R212W | Missense Mutation (SNP) | VAF 45/460 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs762956397; called by muse, mutect2
- ZBTB17 | c.139G>A p.E47K | Missense Mutation (SNP) | VAF 90/832 reads (11%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.129); catalogued as rs753476579; called by muse, mutect2, varscan2
- ZGRF1 | c.2549C>T p.T850I | Missense Mutation (SNP) | VAF 12/115 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.011); catalogued as rs1204339534; called by muse, varscan2
- ZNF135 | c.658G>A p.G220R (on ENST00000313434 / NM_001289401.2; = p.G232R on NM_003436.4) | Missense Mutation (SNP) | VAF 76/578 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.106); catalogued as rs374589646, COSV57881715; called by muse, mutect2, varscan2
- ZNF428 | c.208C>T p.R70C | Missense Mutation (SNP) | VAF 69/711 reads (10%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.942); catalogued as rs759543944, COSV100334614; called by muse, mutect2, varscan2
- ZNF512B | c.2012C>T p.P671L | Missense Mutation (SNP) | VAF 49/373 reads (13%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs375420745; called by muse, mutect2, varscan2
- ZNF536 | c.374G>A p.R125H | Missense Mutation (SNP) | VAF 96/1364 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs866467288, COSV62820141; called by muse, mutect2
- ZNF584 | c.1255G>A p.V419I | Missense Mutation (SNP) | VAF 19/135 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs756765928; called by muse, mutect2
- ZNF707 | c.710G>A p.C237Y | Missense Mutation (SNP) | VAF 10/208 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1554614595, COSV100690592; called by muse, mutect2
- ZNF784 | c.572C>T p.A191V | Missense Mutation (SNP) | VAF 46/349 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as rs1188348891; called by muse, varscan2
- AC011005.1 | c.812C>T p.A271V | Missense Mutation (SNP) | VAF 69/633 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ACBD5 | c.821G>T p.G274V (on ENST00000375888 / NM_001352568.1; = p.G265V on NM_145698.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 19/508 reads (4%) | SIFT tolerated (0.21); PolyPhen benign (0.094); called by muse, mutect2
- ACIN1 | c.699G>A p.Q233= | Splice Region (SNP) | VAF 13/244 reads (5%) | called by muse, mutect2
- ADAMTS4 | c.668T>C p.L223P | Missense Mutation (SNP) | VAF 36/267 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2
- ADAMTS5 | c.583C>T p.R195C | Missense Mutation (SNP) | VAF 35/250 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); called by muse, mutect2, varscan2
- AGFG2 | c.1072G>T p.G358W | Missense Mutation (SNP) | VAF 23/220 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2
- AHNAK | c.10033G>T p.G3345C | Missense Mutation (SNP) | VAF 19/262 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- AL645922.1 | c.2036T>C p.V679A | Missense Mutation (SNP) | VAF 125/1016 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- ANKIB1 | c.241A>C p.T81P | Missense Mutation (SNP) | VAF 37/303 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- ANKRD16 | c.803T>C p.V268A | Missense Mutation (SNP) | VAF 38/319 reads (12%) | SIFT tolerated (0.69); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ARHGEF9 | c.630A>C p.K210N | Missense Mutation (SNP) | VAF 31/292 reads (11%) | SIFT tolerated (0.41); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- ARIH2 | c.424T>C p.C142R | Missense Mutation (SNP) | VAF 29/233 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ASF1A | c.487G>A p.A163T | Missense Mutation (SNP) | VAF 25/441 reads (6%) | SIFT tolerated (0.23); PolyPhen benign (0); called by muse, mutect2
- ASXL1 | c.3397T>C p.S1133P | Missense Mutation (SNP) | VAF 40/318 reads (13%) | SIFT tolerated (0.26); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- ATP6V0A1 | c.256C>A p.P86T | Missense Mutation (SNP) | VAF 34/352 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- AVPR1B | c.856A>G p.I286V | Missense Mutation (SNP) | VAF 26/298 reads (9%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.889); called by muse, mutect2
- BACE2 | c.368A>G p.H123R | Missense Mutation (SNP) | VAF 44/449 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.408); called by muse, mutect2
- BICRAL | c.1327A>G p.M443V | Missense Mutation (SNP) | VAF 62/443 reads (14%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.488); called by muse, mutect2, varscan2
- C2CD4A | c.969C>A p.D323E | Missense Mutation (SNP) | VAF 34/450 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.49); called by muse, mutect2
- C2CD4D | c.662T>C p.L221P | Missense Mutation (SNP) | VAF 29/263 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- CACNA2D3 | c.553A>T p.I185F | Missense Mutation (SNP) | VAF 24/160 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- CARMIL2 | c.433C>A p.P145T | Missense Mutation (SNP) | VAF 52/388 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- CDC42SE2 | c.142A>G p.S48G | Missense Mutation (SNP) | VAF 30/191 reads (16%) | SIFT tolerated (0.44); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- CDHR4 | c.469C>A p.P157T | Missense Mutation (SNP) | VAF 32/366 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.156); called by muse, mutect2
- CDON | c.3386G>A p.S1129N | Missense Mutation (SNP) | VAF 20/468 reads (4%) | SIFT tolerated (0.08); PolyPhen benign (0.015); called by muse, mutect2
- CENPJ | c.1721A>G p.E574G | Missense Mutation (SNP) | VAF 9/92 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CHIT1 | c.1310T>C p.F437S | Missense Mutation (SNP) | VAF 34/327 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.812); called by muse, mutect2, varscan2
- CHST4 | c.939G>T p.K313N | Missense Mutation (SNP) | VAF 48/459 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.776); called by muse, mutect2, varscan2
- CLASRP | c.284del p.P95Lfs*81 | Frame Shift Del (DEL) | VAF 15/95 reads (16%) | called by mutect2, pindel, varscan2
- CLIC5 | c.847G>A p.A283T (on ENST00000185206 / NM_001370649.1; = p.A124T on NM_016929.5) | Missense Mutation (SNP) | VAF 57/666 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.208); called by muse, mutect2
- CNTNAP3 | c.2755+2T>C p.X919_splice | Splice Site (SNP) | VAF 20/578 reads (3%) | called by muse, mutect2
- CPPED1 | c.274A>G p.I92V | Missense Mutation (SNP) | VAF 56/370 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CRB1 | c.4005+5G>T | Splice Region (SNP) | VAF 22/497 reads (4%) | called by muse, mutect2
- CREB3L4 | c.398T>C p.V133A | Missense Mutation (SNP) | VAF 67/517 reads (13%) | SIFT tolerated (0.28); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- CSMD2 | c.2725C>T p.P909S | Missense Mutation (SNP) | VAF 42/292 reads (14%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.696); called by muse, mutect2, varscan2
- CYLD | c.2825C>T p.A942V | Missense Mutation (SNP) | VAF 19/416 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2
- DCN | c.743C>G p.A248G | Missense Mutation (SNP) | VAF 84/413 reads (20%) | SIFT tolerated (0.29); PolyPhen benign (0); called by muse, mutect2, varscan2
- DDOST | c.1195T>C p.Y399H (on ENST00000415136; = p.Y382H on NM_005216.5) | Missense Mutation (SNP) | VAF 72/554 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); called by muse, mutect2, varscan2
- DEPDC5 | c.1108G>T p.G370* | Nonsense Mutation (SNP) | VAF 36/464 reads (8%) | called by muse, mutect2
- EIF2AK4 | c.2048G>A p.R683H | Missense Mutation (SNP) | VAF 57/447 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- EIF2B5 | c.863A>C p.E288A (on ENST00000647909; = p.E280A on NM_003907.3) | Missense Mutation (SNP) | VAF 85/757 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ELAPOR2 | c.1235C>A p.P412H (on ENST00000450689 / NM_001142749.3; = p.P245H on NM_152748.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 11/156 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.967); called by muse, mutect2
- EPS15L1 | c.1987T>C p.F663L | Missense Mutation (SNP) | VAF 45/353 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.197); called by muse, mutect2, varscan2
- ETAA1 | c.1601A>T p.N534I | Missense Mutation (SNP) | VAF 28/132 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.509); called by muse, mutect2, varscan2
- EVA1B | c.475C>A p.L159M | Missense Mutation (SNP) | VAF 33/324 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.066); called by muse, varscan2
- FAM135A | c.4382C>T p.P1461L (on ENST00000370479 / NM_001351599.1; = p.P1248L on NM_020819.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 46/396 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FAM210B | c.295G>A p.V99I | Missense Mutation (SNP) | VAF 31/278 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.406); called by muse, mutect2, varscan2
- FASN | c.505C>T p.Q169* | Nonsense Mutation (SNP) | VAF 74/520 reads (14%) | called by muse, mutect2, varscan2
- FCRL5 | c.1349C>T p.A450V | Missense Mutation (SNP) | VAF 21/255 reads (8%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.992); called by muse, mutect2
- FLNB | c.6469T>C p.F2157L | Missense Mutation (SNP) | VAF 71/669 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- FLRT3 | c.1948T>C p.*650Rext*2 | Nonstop Mutation (SNP) | VAF 12/107 reads (11%) | called by muse, varscan2
- FOSL2 | c.487A>T p.K163* | Nonsense Mutation (SNP) | VAF 113/544 reads (21%) | called by muse, mutect2, varscan2
- FOXD3 | c.254C>T p.A85V | Missense Mutation (SNP) | VAF 12/134 reads (9%) | SIFT tolerated (0.21); PolyPhen benign (0.238); called by muse, mutect2
- FOXH1 | c.599G>T p.G200V | Missense Mutation (SNP) | VAF 6/142 reads (4%) | SIFT tolerated (0.15); PolyPhen benign (0.04); called by muse, mutect2
- FSIP2 | c.985A>G p.T329A | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT tolerated (0.53); PolyPhen benign (0.033); called by muse, mutect2
- FUT1 | c.812A>G p.N271S | Missense Mutation (SNP) | VAF 117/886 reads (13%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- FZD1 | c.1904C>T p.T635M | Missense Mutation (SNP) | VAF 14/127 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.153); called by muse, mutect2, varscan2
- GDF5 | c.1079C>T p.A360V | Missense Mutation (SNP) | VAF 94/992 reads (9%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.76); called by muse, mutect2
- GLP2R | c.365T>C p.L122S | Missense Mutation (SNP) | VAF 73/415 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GLTPD2 | c.457G>A p.A153T | Missense Mutation (SNP) | VAF 64/404 reads (16%) | SIFT tolerated (0.78); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- GLUL | c.908T>C p.F303S | Missense Mutation (SNP) | VAF 22/808 reads (3%) | SIFT tolerated (0.28); PolyPhen benign (0.003); called by muse, mutect2
- GNAS | c.976G>A p.D326N | Missense Mutation (SNP) | VAF 30/232 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.829); called by muse, mutect2, varscan2
- GNAT1 | c.781G>T p.V261L | Missense Mutation (SNP) | VAF 70/726 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.028); called by muse, mutect2
- GRIN2C | c.1403T>C p.V468A | Missense Mutation (SNP) | VAF 81/614 reads (13%) | SIFT tolerated (0.63); PolyPhen benign (0.003); called by mutect2, varscan2
- HEATR5B | c.1813C>T p.Q605* | Nonsense Mutation (SNP) | VAF 78/311 reads (25%) | called by muse, mutect2, varscan2
- HLA-C | c.1016-2A>G p.X339_splice | Splice Site (SNP) | VAF 66/710 reads (9%) | called by muse, mutect2
- HOXA2 | c.180C>A p.N60K | Missense Mutation (SNP) | VAF 77/613 reads (13%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.644); called by muse, mutect2, varscan2
- HSF5 | c.523C>T p.P175S | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.783); called by muse, mutect2, varscan2
- HSPG2 | c.12268A>G p.T4090A | Missense Mutation (SNP) | VAF 55/529 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.523); called by muse, mutect2, varscan2
- IGSF22 | c.1004A>G p.K335R | Missense Mutation (SNP) | VAF 18/236 reads (8%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.995); called by muse, mutect2
- IL16 | c.2254G>A p.G752S (on ENST00000302987 / NM_172217.5; = p.G51S on NM_004513.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/343 reads (5%) | SIFT tolerated (0.94); PolyPhen benign (0.006); called by muse, mutect2
- IPO13 | c.1217A>G p.D406G | Missense Mutation (SNP) | VAF 54/512 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.276); called by muse, mutect2, varscan2
- IRF6 | c.175-2A>G p.X59_splice | Splice Site (SNP) | VAF 71/513 reads (14%) | called by muse, mutect2, varscan2
- IRX1 | c.232G>A p.A78T | Missense Mutation (SNP) | VAF 32/262 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- IRX2 | c.1330C>T p.R444W | Missense Mutation (SNP) | VAF 75/511 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.803); called by muse, mutect2, varscan2
- ITPR1 | c.1634G>A p.R545Q (on ENST00000354582; = p.R530Q on NM_002222.7) | Missense Mutation (SNP) | VAF 33/306 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.559); called by muse, mutect2, varscan2
- JAK2 | c.3291+2T>C p.X1097_splice | Splice Site (SNP) | VAF 25/156 reads (16%) | called by muse, mutect2, varscan2
- JMJD1C | c.416T>A p.L139* | Nonsense Mutation (SNP) | VAF 24/203 reads (12%) | called by muse, mutect2, varscan2
- JMJD6 | c.602A>G p.Q201R | Missense Mutation (SNP) | VAF 107/703 reads (15%) | SIFT tolerated (0.63); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- KCNT1 | c.3247A>C p.S1083R (on ENST00000488444; = p.S1109R on NM_020822.3) | Missense Mutation (SNP) | VAF 83/785 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.824); called by muse, mutect2, varscan2
- LAMB2 | c.1166G>A p.C389Y | Missense Mutation (SNP) | VAF 54/592 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- LATS1 | c.2350T>C p.Y784H | Missense Mutation (SNP) | VAF 12/147 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- LRRC8A | c.452C>T p.S151L | Missense Mutation (SNP) | VAF 51/498 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LRSAM1 | c.898A>G p.K300E | Missense Mutation (SNP) | VAF 36/542 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.056); called by muse, mutect2
- LZTS2 | c.1874A>G p.Y625C | Missense Mutation (SNP) | VAF 28/434 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.061); called by muse, mutect2
- MAGEC1 | c.2866T>C p.F956L | Missense Mutation (SNP) | VAF 37/288 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MAP2K7 | c.404G>A p.W135* | Nonsense Mutation (SNP) | VAF 63/374 reads (17%) | called by muse, mutect2, varscan2
- MAP7D3 | c.54G>T p.E18D | Missense Mutation (SNP) | VAF 55/433 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0.262); called by muse, mutect2, varscan2
- METTL22 | c.1010G>T p.R337M | Missense Mutation (SNP) | VAF 61/400 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- METTL5 | c.323A>G p.D108G | Missense Mutation (SNP) | VAF 49/272 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.309); called by muse, mutect2, varscan2
- MEX3A | c.1013G>A p.S338N | Missense Mutation (SNP) | VAF 75/647 reads (12%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.527); called by muse, mutect2, varscan2
- MFN2 | c.1606G>A p.D536N | Missense Mutation (SNP) | VAF 92/990 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); called by muse, mutect2
- MGAT4B | c.928C>A p.L310M | Missense Mutation (SNP) | VAF 62/388 reads (16%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- MIB1 | c.1087C>T p.L363F | Missense Mutation (SNP) | VAF 20/178 reads (11%) | SIFT tolerated (0.65); PolyPhen probably damaging (0.916); called by muse, mutect2
- MIOX | c.814C>A p.Q272K | Missense Mutation (SNP) | VAF 66/627 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.373); called by muse, mutect2, varscan2
- MMP21 | c.952G>A p.D318N | Missense Mutation (SNP) | VAF 40/366 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MOSPD2 | c.319T>A p.L107M | Missense Mutation (SNP) | VAF 27/154 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- MYCBP2 | c.7404+1G>C p.X2468_splice (on ENST00000357337; = p.X2506_splice on NM_015057.5) | Splice Site (SNP) | VAF 23/178 reads (13%) | called by muse, mutect2, varscan2
- MYCBPAP | c.2824T>C p.*942Rext*? | Nonstop Mutation (SNP) | VAF 42/316 reads (13%) | called by muse, mutect2, varscan2
- MYO15A | c.2456C>T p.S819L | Missense Mutation (SNP) | VAF 21/182 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.417); called by muse, mutect2, varscan2
- MYOM3 | c.1971-2A>G p.X657_splice | Splice Site (SNP) | VAF 14/125 reads (11%) | called by muse, mutect2, varscan2
- NKD2 | c.1301A>G p.H434R | Missense Mutation (SNP) | VAF 33/305 reads (11%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.036); called by muse, varscan2
- NOS1 | c.852G>T p.Q284H | Missense Mutation (SNP) | VAF 37/157 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.372); called by muse, mutect2, varscan2
- NOTCH3 | c.6049C>T p.H2017Y | Missense Mutation (SNP) | VAF 54/620 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- NUB1 | c.412T>C p.S138P | Missense Mutation (SNP) | VAF 17/165 reads (10%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.522); called by muse, mutect2, varscan2
- NUP98 | c.4388C>A p.A1463D (on ENST00000359171 / NM_001365126.1; = p.A1446D on NM_016320.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 52/447 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OCSTAMP | c.1288G>A p.A430T | Missense Mutation (SNP) | VAF 73/586 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- OFD1 | c.1822A>T p.I608F | Missense Mutation (SNP) | VAF 67/546 reads (12%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.6); called by muse, mutect2, varscan2
- OTUD4 | c.13G>A p.V5I | Missense Mutation (SNP) | VAF 12/374 reads (3%) | SIFT tolerated, low confidence (0.11); called by muse, mutect2
- PAK6 | c.1552C>T p.H518Y | Missense Mutation (SNP) | VAF 36/394 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- PATJ | c.4253A>G p.Q1418R | Missense Mutation (SNP) | VAF 18/220 reads (8%) | SIFT tolerated (0.29); PolyPhen benign (0.224); called by muse, mutect2
- PAXX | c.575+2T>C p.X192_splice | Splice Site (SNP) | VAF 54/536 reads (10%) | called by muse, mutect2, varscan2
- PCNX3 | c.2477T>C p.L826P | Missense Mutation (SNP) | VAF 30/397 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.795); called by muse, mutect2
- PDZD11 | c.328G>T p.A110S | Missense Mutation (SNP) | VAF 33/482 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.209); called by muse, mutect2
- PIDD1 | c.2656C>T p.R886C | Missense Mutation (SNP) | VAF 34/406 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); called by muse, mutect2
- PLCL1 | c.1498C>T p.Q500* | Nonsense Mutation (SNP) | VAF 10/186 reads (5%) | called by muse, mutect2
- PLCXD1 | c.106C>A p.L36I | Missense Mutation (SNP) | VAF 39/454 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.905); called by muse, mutect2
- PLEKHM3 | c.506A>T p.Q169L | Missense Mutation (SNP) | VAF 44/616 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.01); called by muse, mutect2
- PPFIA4 | c.3445C>T p.R1149C (on ENST00000447715; = p.R1150C on NM_001304331.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/88 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.155); called by muse, mutect2, varscan2
- PPP1R9B | c.1073C>T p.A358V | Missense Mutation (SNP) | VAF 22/534 reads (4%) | SIFT tolerated (0.25); PolyPhen benign (0.024); called by muse, mutect2
- PPP2R3B | c.100G>A p.D34N | Missense Mutation (SNP) | VAF 41/562 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.236); called by muse, mutect2
- PSMD8 | c.707T>C p.L236P | Missense Mutation (SNP) | VAF 17/197 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- RFC3 | c.346G>A p.A116T | Missense Mutation (SNP) | VAF 14/176 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2
- ROCK1 | c.1410+2T>C p.X470_splice | Splice Site (SNP) | VAF 43/378 reads (11%) | called by muse, mutect2, varscan2
- RPS15 | c.377T>C p.V126A | Missense Mutation (SNP) | VAF 143/1089 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.8); called by muse, mutect2, varscan2
- RYR3 | c.2222T>C p.V741A | Missense Mutation (SNP) | VAF 46/585 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2
- SAG | c.947T>C p.I316T | Missense Mutation (SNP) | VAF 25/275 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.408); called by muse, mutect2
- SH3RF1 | c.2293G>T p.G765C | Missense Mutation (SNP) | VAF 37/320 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.87); called by muse, mutect2, varscan2
- SLC25A28 | c.215T>C p.V72A | Missense Mutation (SNP) | VAF 29/368 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.199); called by muse, mutect2
- SLC35A1 | c.826G>A p.A276T | Missense Mutation (SNP) | VAF 88/758 reads (12%) | SIFT tolerated (1); PolyPhen possibly damaging (0.487); called by muse, mutect2, varscan2
- SLC6A19 | c.868T>C p.S290P | Missense Mutation (SNP) | VAF 52/583 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- SMARCA4 | c.810del p.M272Cfs*31 | Frame Shift Del (DEL) | VAF 49/456 reads (11%) | called by mutect2, pindel, varscan2
- SNX1 | c.1501C>A p.L501I | Missense Mutation (SNP) | VAF 14/150 reads (9%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.808); called by muse, mutect2
- SPDYE4 | c.661G>T p.A221S | Missense Mutation (SNP) | VAF 20/489 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.801); called by muse, mutect2
- SPO11 | c.28G>A p.A10T | Missense Mutation (SNP) | VAF 17/240 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.955); called by muse, mutect2
- ST14 | c.587T>C p.V196A | Missense Mutation (SNP) | VAF 50/507 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.524); called by muse, mutect2
- SYNE1 | c.1972A>G p.T658A (on ENST00000367255 / NM_182961.4; = p.T665A on NM_033071.3) | Missense Mutation (SNP) | VAF 38/614 reads (6%) | SIFT tolerated (0.4); PolyPhen benign (0); called by muse, mutect2
- TBCB | c.333A>C p.Q111H | Missense Mutation (SNP) | VAF 19/339 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.289); called by muse, mutect2
- TENM1 | c.3282G>A p.W1094* | Nonsense Mutation (SNP) | VAF 19/131 reads (15%) | called by muse, mutect2, varscan2
- TENM2 | c.6746A>G p.D2249G (on ENST00000518659 / NM_001122679.2; = p.D2010G on NM_001080428.3) | Missense Mutation (SNP) | VAF 45/412 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TFDP1 | c.60G>T p.Q20H | Missense Mutation (SNP) | VAF 26/340 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.751); called by muse, mutect2
- TFEC | c.114G>A p.M38I | Missense Mutation (SNP) | VAF 25/243 reads (10%) | SIFT tolerated (0.42); PolyPhen benign (0); called by muse, mutect2, varscan2
- TGFBR1 | c.316T>C p.C106R | Missense Mutation (SNP) | VAF 40/410 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TGFBR1 | c.838T>C p.S280P | Missense Mutation (SNP) | VAF 46/508 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); called by muse, mutect2
- TGM2 | c.254A>C p.E85A | Missense Mutation (SNP) | VAF 67/606 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.232); called by muse, mutect2, varscan2
- TMEM214 | c.431A>G p.D144G | Missense Mutation (SNP) | VAF 93/477 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TNFRSF25 | c.1130A>C p.E377A | Missense Mutation (SNP) | VAF 62/594 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- TNK2 | c.679G>A p.G227R | Missense Mutation (SNP) | VAF 68/487 reads (14%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.861); called by muse, mutect2, varscan2
- TOR4A | c.592G>A p.V198M | Missense Mutation (SNP) | VAF 35/421 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- TPM3 | c.27G>A p.M9I | Missense Mutation (SNP) | VAF 92/1005 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- TRAF7 | c.1382T>C p.I461T | Missense Mutation (SNP) | VAF 45/361 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.658); called by muse, mutect2, varscan2
- TRIM7 | c.347A>G p.H116R | Missense Mutation (SNP) | VAF 19/240 reads (8%) | SIFT tolerated (0.83); PolyPhen benign (0); called by muse, mutect2
- TUBGCP5 | c.1242A>C p.K414N | Missense Mutation (SNP) | VAF 70/729 reads (10%) | SIFT tolerated (0.17); PolyPhen benign (0.312); called by muse, mutect2
- TXNDC2 | c.952C>A p.P318T (on ENST00000306084 / NM_001098529.2; = p.P251T on NM_032243.6) | Missense Mutation (SNP) | VAF 58/1255 reads (5%) | SIFT tolerated (0.39); PolyPhen benign (0.063); called by muse, mutect2
- UGT1A6 | c.1444T>G p.W482G | Missense Mutation (SNP) | VAF 76/792 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- USP17L4 | c.977C>T p.A326V | Missense Mutation (SNP) | VAF 107/1169 reads (9%) | SIFT tolerated (0.23); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- USP19 | c.1117C>T p.R373C | Missense Mutation (SNP) | VAF 22/224 reads (10%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.814); called by muse, mutect2
- VIL1 | c.106A>G p.T36A | Missense Mutation (SNP) | VAF 40/385 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- VPS51 | c.1109G>A p.R370Q | Missense Mutation (SNP) | VAF 89/840 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.243); called by muse, mutect2
- VWA7 | c.535T>C p.W179R | Missense Mutation (SNP) | VAF 27/321 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- VWF | c.842T>C p.V281A | Missense Mutation (SNP) | VAF 66/773 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.12); called by muse, mutect2
- WDR41 | c.1261A>G p.T421A | Missense Mutation (SNP) | VAF 26/211 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.434); called by muse, mutect2, varscan2
- XDH | c.2657T>C p.M886T | Missense Mutation (SNP) | VAF 82/888 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.253); called by muse, mutect2
- ZC3H7B | c.565G>A p.A189T | Missense Mutation (SNP) | VAF 43/376 reads (11%) | SIFT tolerated (0.57); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ZKSCAN4 | c.243G>A p.W81* | Nonsense Mutation (SNP) | VAF 23/669 reads (3%) | called by muse, mutect2
- ZNF224 | c.901T>C p.S301P | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.864); called by muse, mutect2, varscan2
- ZNF572 | c.152C>A p.P51H | Missense Mutation (SNP) | VAF 21/200 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.125); called by muse, mutect2
- ZNF821 | c.877C>T p.R293W (on ENST00000425432 / NM_001376297.1; = p.R251W on NM_017530.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 73/702 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- AARS2 | c.6A>G p.A2= | Silent (SNP) | VAF 74/722 reads (10%) | catalogued as rs1467763767; called by muse, mutect2
- ADPRHL1 | c.36C>T p.S12= | Silent (SNP) | VAF 64/530 reads (12%) | catalogued as rs1292713643; called by muse, mutect2, varscan2
- AHNAK2 | c.7446G>A p.R2482= | Silent (SNP) | VAF 190/917 reads (21%) | catalogued as rs746879559; called by muse, mutect2, varscan2
- APAF1 | c.3501G>A p.P1167= (on ENST00000551964 / NM_181861.2; = p.P1113= on NM_001160.3) | Silent (SNP) | VAF 30/628 reads (5%) | catalogued as rs368589663, COSV59669714; called by muse, mutect2
- ARFGEF3 | c.3246G>A p.L1082= | Silent (SNP) | VAF 9/129 reads (7%) | called by muse, mutect2
- ARHGAP31 | c.2013G>A p.S671= | Silent (SNP) | VAF 54/530 reads (10%) | catalogued as rs367819044, COSV51789399; called by muse, mutect2, varscan2
- ARHGEF16 | c.1098C>T p.H366= | Silent (SNP) | VAF 41/401 reads (10%) | catalogued as rs764714977; called by muse, mutect2, varscan2
- ARID4B | c.219T>C p.G73= | Silent (SNP) | VAF 20/220 reads (9%) | called by muse, mutect2
- C10orf82 | c.213C>T p.S71= | Silent (SNP) | VAF 32/252 reads (13%) | catalogued as rs374577819; called by muse, mutect2, varscan2
- CACNA2D3 | c.744C>T p.I248= | Silent (SNP) | VAF 27/213 reads (13%) | called by muse, mutect2, varscan2
- CDC23 | c.153T>C p.S51= | Silent (SNP) | VAF 52/342 reads (15%) | called by muse, mutect2, varscan2
- CERS3 | c.936G>A p.Q312= | Silent (SNP) | VAF 18/358 reads (5%) | called by muse, mutect2
- CHMP5 | c.78T>C p.S26= | Silent (SNP) | VAF 14/178 reads (8%) | catalogued as rs1023861534; called by muse, mutect2
- CIAO3 | c.405T>C p.T135= | Silent (SNP) | VAF 48/461 reads (10%) | called by muse, mutect2, varscan2
- CMA1 | c.366G>A p.L122= | Silent (SNP) | VAF 58/280 reads (21%) | called by muse, mutect2
- COL5A1 | c.3927A>C p.G1309= | Silent (SNP) | VAF 27/411 reads (7%) | called by muse, mutect2
- CPVL | c.1111T>C p.L371= | Silent (SNP) | VAF 42/379 reads (11%) | called by muse, mutect2, varscan2
- CSNK1G1 | c.708C>T p.A236= | Silent (SNP) | VAF 40/523 reads (8%) | called by muse, mutect2
- DAW1 | c.390G>A p.L130= | Silent (SNP) | VAF 33/360 reads (9%) | called by muse, mutect2
- DNAH10 | c.7575T>C p.T2525= (on ENST00000409039; = p.T2464= on NM_207437.3) | Silent (SNP) | VAF 26/345 reads (8%) | called by muse, mutect2
- EPN3 | c.1350T>C p.P450= | Silent (SNP) | VAF 33/272 reads (12%) | called by muse, mutect2, varscan2
- EYS | c.6208C>T p.L2070= | Silent (SNP) | VAF 21/177 reads (12%) | called by muse, mutect2
- FAM160B2 | c.2067G>A p.Q689= | Silent (SNP) | VAF 56/446 reads (13%) | catalogued as rs1457482091; called by muse, mutect2, varscan2
- FAM170B | c.135G>A p.S45= | Silent (SNP) | VAF 12/114 reads (11%) | called by muse, mutect2, varscan2
- FAM50A | c.483C>T p.D161= | Silent (SNP) | VAF 39/400 reads (10%) | catalogued as rs782616761; called by muse, mutect2
- FGF23 | c.42C>T p.C14= | Silent (SNP) | VAF 89/706 reads (13%) | called by muse, mutect2, varscan2
- FZD7 | c.720C>T p.N240= | Silent (SNP) | VAF 48/452 reads (11%) | catalogued as COSV53808472; called by muse, mutect2
- GABRA2 | c.576A>G p.S192= | Silent (SNP) | VAF 18/208 reads (9%) | catalogued as rs200053930; called by muse, mutect2
- GCC2 | c.171A>G p.E57= | Silent (SNP) | VAF 81/306 reads (26%) | called by muse, mutect2, varscan2
- GDF1 | c.459G>A p.A153= | Silent (SNP) | VAF 41/265 reads (15%) | called by muse, mutect2, varscan2
- HM13 | c.48C>T p.G16= | Silent (SNP) | VAF 120/1046 reads (11%) | called by muse, mutect2, varscan2
- IGSF9B | c.3912G>A p.T1304= | Silent (SNP) | VAF 4/26 reads (15%) | catalogued as rs1233430994, COSV58065150; called by muse, mutect2
- IGSF9B | c.1854G>A p.P618= | Silent (SNP) | VAF 75/617 reads (12%) | catalogued as rs936155611; called by muse, mutect2, varscan2
- IL4I1 | c.1491G>A p.A497= | Silent (SNP) | VAF 23/218 reads (11%) | catalogued as rs1277285483, COSV55577025; called by muse, mutect2
- INPP5B | c.81G>A p.E27= | Silent (SNP) | VAF 26/354 reads (7%) | catalogued as COSV65958048; called by muse, mutect2
- IRX1 | c.787C>A p.R263= | Silent (SNP) | VAF 36/326 reads (11%) | catalogued as COSV57357969; called by muse, mutect2, varscan2
- ITPKB | c.780T>C p.G260= | Silent (SNP) | VAF 16/258 reads (6%) | called by muse, mutect2
- ITPR1 | c.6543C>T p.D2181= (on ENST00000354582; = p.D2126= on NM_002222.7) | Silent (SNP) | VAF 14/196 reads (7%) | catalogued as rs578051224, COSV56990162; called by muse, mutect2
- ITPR3 | c.3459C>T p.D1153= | Silent (SNP) | VAF 34/342 reads (10%) | catalogued as rs377753110; called by muse, mutect2, varscan2
- JMJD7-PLA2G4B | c.1674C>T p.C558= | Silent (SNP) | VAF 54/609 reads (9%) | catalogued as rs754262196, COSV58022293; called by muse, mutect2
- KAZN | c.150G>A p.S50= | Silent (SNP) | VAF 37/355 reads (10%) | catalogued as rs374201920; called by muse, mutect2, varscan2
- LARS1 | c.2241T>C p.G747= (on ENST00000394434 / NM_020117.11; = p.G720= on NM_016460.3) | Silent (SNP) | VAF 28/322 reads (9%) | called by muse, mutect2
- LIPC | c.381C>T p.H127= | Silent (SNP) | VAF 70/576 reads (12%) | catalogued as rs776118661; called by muse, mutect2, varscan2
- MACF1 | c.9666T>C p.S3222= | Silent (SNP) | VAF 22/164 reads (13%) | called by muse, mutect2, varscan2
- MAP3K1 | c.3609C>T p.P1203= | Silent (SNP) | VAF 12/118 reads (10%) | catalogued as rs1554035881; ClinVar: likely benign; called by muse, mutect2, varscan2
- MAPKBP1 | c.1437C>T p.R479= (on ENST00000456763 / NM_001128608.2; = p.R473= on NM_014994.3) | Silent (SNP) | VAF 26/358 reads (7%) | catalogued as rs150429615; called by muse, mutect2
- MAVS | c.1461G>A p.A487= | Silent (SNP) | VAF 49/439 reads (11%) | catalogued as rs767756615, COSV63926543, COSV63927348; called by muse, mutect2, varscan2
- MCC | c.495G>A p.Q165= | Silent (SNP) | VAF 76/684 reads (11%) | called by muse, mutect2, varscan2
- MED1 | c.1764G>A p.S588= | Silent (SNP) | VAF 83/692 reads (12%) | catalogued as rs755797231; called by muse, mutect2, varscan2
- MED13L | c.5712T>C p.L1904= | Silent (SNP) | VAF 150/805 reads (19%) | called by muse, mutect2, varscan2
- MICAL1 | c.2920C>T p.L974= | Silent (SNP) | VAF 20/674 reads (3%) | called by muse, mutect2
- MYO18A | c.2334C>T p.S778= | Silent (SNP) | VAF 30/206 reads (15%) | called by muse, mutect2, varscan2
- MYO18B | c.3657A>G p.P1219= | Silent (SNP) | VAF 97/847 reads (11%) | called by muse, varscan2
- N4BP2 | c.270T>A p.T90= | Silent (SNP) | VAF 8/104 reads (8%) | catalogued as COSV99789452; called by muse, mutect2
- NAV2 | c.642C>T p.A214= | Silent (SNP) | VAF 34/580 reads (6%) | catalogued as rs764794415; called by muse, mutect2
- NAXD | c.84G>A p.G28= | Silent (SNP) | VAF 22/157 reads (14%) | catalogued as COSV100010719; called by muse, mutect2, varscan2
- NECTIN1 | c.1272C>T p.D424= | Silent (SNP) | VAF 46/548 reads (8%) | catalogued as rs200452076; called by muse, mutect2
- NEK8 | c.354T>C p.H118= | Silent (SNP) | VAF 96/834 reads (12%) | called by muse, mutect2, varscan2
- NIPBL | c.5100A>G p.S1700= | Silent (SNP) | VAF 54/523 reads (10%) | catalogued as rs1295213842; called by muse, mutect2, varscan2
- NIPSNAP3A | c.399A>G p.P133= | Silent (SNP) | VAF 51/410 reads (12%) | called by muse, mutect2, varscan2
- NLGN2 | c.1935G>A p.P645= | Silent (SNP) | VAF 35/192 reads (18%) | catalogued as rs367900044; called by muse, mutect2, varscan2
- NLRP4 | c.519G>A p.S173= | Silent (SNP) | VAF 46/470 reads (10%) | catalogued as rs749484722, COSV56709907; called by muse, mutect2, varscan2
- NR1D1 | c.708G>A p.P236= | Silent (SNP) | VAF 56/636 reads (9%) | catalogued as rs147503529; called by muse, mutect2
- NUTM1 | c.3126C>A p.A1042= | Silent (SNP) | VAF 40/496 reads (8%) | called by muse, mutect2
- OR2A1 | c.276C>A p.S92= | Silent (SNP) | VAF 118/1682 reads (7%) | called by muse, mutect2
- P3H1 | c.1671G>A p.T557= | Silent (SNP) | VAF 42/432 reads (10%) | catalogued as rs772912578, COSV52531745; called by muse, mutect2
- PAPSS1 | c.360T>C p.F120= | Silent (SNP) | VAF 54/525 reads (10%) | catalogued as rs375007289; called by muse, mutect2, varscan2
- PCDH10 | c.597C>T p.Y199= | Silent (SNP) | VAF 18/182 reads (10%) | called by muse, mutect2
- PCDHA6 | c.1887C>T p.G629= | Silent (SNP) | VAF 85/726 reads (12%) | catalogued as rs782161217; called by muse, mutect2, varscan2
- PLA2G3 | c.1161C>T p.S387= | Silent (SNP) | VAF 28/212 reads (13%) | catalogued as rs777451080; called by muse, mutect2, varscan2
- PLEC | c.10791C>T p.H3597= (on ENST00000322810 / NM_201380.4; = p.H3487= on NM_000445.5) | Silent (SNP) | VAF 38/384 reads (10%) | catalogued as rs371407635; called by muse, mutect2
- PLEKHN1 | c.282A>G p.G94= | Silent (SNP) | VAF 38/390 reads (10%) | called by muse, mutect2
- PODXL | c.582G>A p.S194= | Silent (SNP) | VAF 81/699 reads (12%) | catalogued as rs774359433; called by muse, mutect2, varscan2
- PPP1R8 | c.207G>T p.R69= | Silent (SNP) | VAF 16/318 reads (5%) | called by muse, mutect2
- PRG4 | c.4089C>T p.D1363= | Silent (SNP) | VAF 42/371 reads (11%) | catalogued as rs145515394; called by muse, mutect2, varscan2
- PRPF38B | c.477G>A p.A159= | Silent (SNP) | VAF 22/212 reads (10%) | catalogued as rs770782317, COSV64223659; called by muse, mutect2
- PSMD1 | c.867A>G p.G289= | Silent (SNP) | VAF 42/552 reads (8%) | called by muse, mutect2
- PTPRC | c.2499A>G p.K833= | Silent (SNP) | VAF 69/723 reads (10%) | catalogued as rs975797535; called by muse, mutect2
- PUDP | c.66T>C p.T22= | Silent (SNP) | VAF 33/266 reads (12%) | called by muse, mutect2
- RAB14 | c.183A>G p.K61= | Silent (SNP) | VAF 64/494 reads (13%) | called by muse, mutect2, varscan2
- RAD54L2 | c.978G>A p.T326= | Silent (SNP) | VAF 27/273 reads (10%) | catalogued as rs753671462; called by muse, mutect2
- RBBP7 | c.903T>C p.D301= | Silent (SNP) | VAF 35/278 reads (13%) | called by muse, mutect2, varscan2
- RET | c.2226G>A p.T742= | Silent (SNP) | VAF 62/497 reads (12%) | catalogued as rs762876946, COSV100394888, COSV60692122; ClinVar: likely benign / benign; called by muse, mutect2, varscan2
- RHOBTB1 | c.1209C>T p.D403= | Silent (SNP) | VAF 20/612 reads (3%) | catalogued as rs1228015121; called by muse, mutect2
- RSL1D1 | c.445C>T p.L149= | Silent (SNP) | VAF 31/441 reads (7%) | called by muse, mutect2
- SAE1 | c.399C>T p.C133= | Silent (SNP) | VAF 25/182 reads (14%) | catalogued as COSV54295146; called by muse, mutect2, varscan2
- SCART1 | c.1332C>T p.D444= | Silent (SNP) | VAF 14/146 reads (10%) | called by muse, mutect2
- SEMA5A | c.2442C>T p.P814= | Silent (SNP) | VAF 82/850 reads (10%) | catalogued as rs769162684, COSV101228776, COSV66803970; called by muse, mutect2
- SLC12A7 | c.597C>T p.G199= | Silent (SNP) | VAF 60/536 reads (11%) | called by muse, mutect2, varscan2
- SLC1A6 | c.954C>T p.I318= | Silent (SNP) | VAF 18/153 reads (12%) | called by muse, mutect2, varscan2
- SLC22A18 | c.297C>A p.A99= | Silent (SNP) | VAF 44/526 reads (8%) | called by muse, mutect2
- SLC22A6 | c.585G>A p.S195= | Silent (SNP) | VAF 36/552 reads (7%) | catalogued as rs778657112; called by muse, mutect2
- SLC7A6 | c.336C>T p.Y112= | Silent (SNP) | VAF 95/579 reads (16%) | catalogued as rs144605306; called by muse, mutect2, varscan2
- SMCR8 | c.1155A>G p.K385= | Silent (SNP) | VAF 47/297 reads (16%) | catalogued as rs1171124180; called by muse, mutect2, varscan2
- SMYD1 | c.390C>T p.D130= | Silent (SNP) | VAF 61/269 reads (23%) | catalogued as rs771497079, COSV70225065; called by muse, mutect2, varscan2
- SON | c.4833T>C p.G1611= | Silent (SNP) | VAF 24/369 reads (7%) | called by muse, mutect2
- SPTA1 | c.2517G>T p.L839= | Silent (SNP) | VAF 86/850 reads (10%) | called by muse, mutect2, varscan2
- SPTBN5 | c.6240G>A p.S2080= | Silent (SNP) | VAF 81/720 reads (11%) | catalogued as rs768341497, COSV58025373; called by muse, mutect2, varscan2
- STAG3 | c.1228C>T p.L410= | Silent (SNP) | VAF 88/938 reads (9%) | called by muse, mutect2
- SUSD2 | c.1695A>G p.S565= | Silent (SNP) | VAF 87/598 reads (15%) | called by muse, mutect2, varscan2
- SYNE2 | c.45C>A p.S15= | Silent (SNP) | VAF 49/279 reads (18%) | called by muse, mutect2, varscan2
- TANC1 | c.2478C>T p.D826= | Silent (SNP) | VAF 45/201 reads (22%) | catalogued as rs1452544557; called by muse, mutect2, varscan2
- TCF15 | c.16C>T p.L6= | Silent (SNP) | VAF 11/111 reads (10%) | catalogued as rs1362491870; called by muse, mutect2
- TELO2 | c.2502C>T p.P834= | Silent (SNP) | VAF 54/369 reads (15%) | catalogued as rs776080837; called by muse, mutect2, varscan2
- TENM4 | c.3171C>T p.C1057= | Silent (SNP) | VAF 10/146 reads (7%) | catalogued as rs1400148880; called by muse, mutect2
- TMEM131L | c.2235C>T p.P745= | Silent (SNP) | VAF 43/288 reads (15%) | catalogued as rs200199904; called by muse, mutect2, varscan2
- TMEM209 | c.1002A>G p.S334= | Silent (SNP) | VAF 26/192 reads (14%) | called by muse, mutect2, varscan2
- TMEM43 | c.663T>C p.R221= | Silent (SNP) | VAF 47/414 reads (11%) | called by muse, mutect2, varscan2
- TNFRSF1A | c.1032C>T p.S344= | Silent (SNP) | VAF 19/297 reads (6%) | called by muse, mutect2
- TRADD | c.585G>A p.P195= | Silent (SNP) | VAF 62/540 reads (11%) | catalogued as rs1415309663, COSV50757919; called by mutect2, varscan2
- TRIM63 | c.921C>T p.F307= | Silent (SNP) | VAF 34/346 reads (10%) | catalogued as COSV65328917; called by muse, mutect2
- TTC28 | c.6960C>A p.P2320= | Silent (SNP) | VAF 37/384 reads (10%) | catalogued as COSV67416297; called by muse, mutect2
- UNC13A | c.3444C>T p.F1148= | Silent (SNP) | VAF 43/333 reads (13%) | catalogued as rs570146186; called by muse, mutect2, varscan2
- USH2A | c.8754G>A p.V2918= | Silent (SNP) | VAF 44/462 reads (10%) | called by muse, mutect2
- USP35 | c.624C>T p.A208= | Silent (SNP) | VAF 12/150 reads (8%) | catalogued as rs750266219; called by muse, mutect2
- VWA5B1 | c.1668C>T p.P556= | Silent (SNP) | VAF 46/554 reads (8%) | catalogued as rs1242095215; called by muse, mutect2
- ZBTB48 | c.1632T>C p.H544= | Silent (SNP) | VAF 16/146 reads (11%) | called by muse, mutect2
- ZFHX3 | c.888G>A p.S296= | Silent (SNP) | VAF 23/419 reads (5%) | catalogued as rs377655061; called by muse, mutect2
- ZFPM2 | c.1386A>G p.K462= | Silent (SNP) | VAF 118/1030 reads (11%) | called by muse, mutect2, varscan2
- ZIC1 | c.39C>T p.G13= | Silent (SNP) | VAF 24/256 reads (9%) | called by muse, mutect2
- ZNF536 | c.1830C>T p.H610= | Silent (SNP) | VAF 57/511 reads (11%) | catalogued as rs771230573, COSV62830782; called by muse, mutect2, varscan2
- ZNF736 | c.166C>T p.L56= | Silent (SNP) | VAF 69/593 reads (12%) | called by muse, mutect2, varscan2
- AC021218.1 | n.944C>A | RNA (SNP) | VAF 13/102 reads (13%) | called by muse, mutect2, varscan2
- ACSBG1 | c.132-4504del | Intron (DEL) | VAF 29/283 reads (10%) | catalogued as rs937268580; called by mutect2, pindel, varscan2
- ADAM33 | c.2241-76A>T | Intron (SNP) | VAF 30/416 reads (7%) | called by muse, mutect2
- ADM2 | c.*47C>T | 3'UTR (SNP) | VAF 48/423 reads (11%) | catalogued as rs1352929930; called by muse, mutect2, varscan2
- ANK2 | c.11611-528G>T | Intron (SNP) | VAF 43/385 reads (11%) | called by muse, mutect2, varscan2
- AP000769.3 | chr11:65502315 C>A | 5'Flank (SNP) | VAF 34/210 reads (16%) | called by muse, mutect2, varscan2
- ARFGAP2 | c.*8T>G | 3'UTR (SNP) | VAF 10/95 reads (11%) | called by muse, mutect2, varscan2
- ATAD3C | c.*170C>T | 3'UTR (SNP) | VAF 6/25 reads (24%) | catalogued as rs564888238; called by muse, mutect2, varscan2
- BTBD11 | c.1491-175A>G | Intron (SNP) | VAF 76/471 reads (16%) | called by muse, mutect2
- C19orf12 | c.*287C>T | 3'UTR (SNP) | VAF 144/1230 reads (12%) | catalogued as rs996766909; called by muse, mutect2, varscan2
- C9orf153 | c.-2C>T | 5'UTR (SNP) | VAF 45/360 reads (13%) | catalogued as rs779590719, COSV59251420; called by muse, mutect2, varscan2
- CNIH2 | c.82-819C>T | Intron (SNP) | VAF 52/483 reads (11%) | called by muse, mutect2, varscan2
- CPLANE1 | c.*3527C>T | 3'UTR (SNP) | VAF 45/385 reads (12%) | catalogued as rs1396140286; called by muse, mutect2, varscan2
- CTSK | c.-1-495C>T | Intron (SNP) | VAF 27/344 reads (8%) | catalogued as rs908212829; called by muse, mutect2
- DMTN | c.-70C>T | 5'UTR (SNP) | VAF 31/455 reads (7%) | called by muse, mutect2
- DPYS | c.-34C>T | 5'UTR (SNP) | VAF 6/85 reads (7%) | called by muse, mutect2
- DYNC1H1 | c.13813-21T>C | Intron (SNP) | VAF 170/876 reads (19%) | called by muse, mutect2, varscan2
- EGF | c.1576-51T>C | Intron (SNP) | VAF 29/261 reads (11%) | called by muse, mutect2, varscan2
- FAM217A | c.-82C>T | 5'UTR (SNP) | VAF 18/168 reads (11%) | catalogued as rs902801457, COSV99212675; called by muse, mutect2, varscan2
- FLNB | c.7622-47G>A | Intron (SNP) | VAF 32/322 reads (10%) | called by muse, mutect2
- FOXP2 | c.*860C>T | 3'UTR (SNP) | VAF 53/424 reads (13%) | catalogued as COSV63483636; called by muse, mutect2, varscan2
- GAB1 | c.73-19566G>A | Intron (SNP) | VAF 69/720 reads (10%) | catalogued as rs1560739825; called by muse, mutect2
- GABRA1 | c.-4C>T | 5'UTR (SNP) | VAF 90/661 reads (14%) | catalogued as rs375475234; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- HELZ2 | c.570+170C>A | Intron (SNP) | VAF 41/959 reads (4%) | called by muse, mutect2
- HLA-C | c.1048+12C>T | Intron (SNP) | VAF 41/633 reads (6%) | catalogued as rs767852739; called by muse, mutect2
- HNMT | c.190+11104G>A | Intron (SNP) | VAF 126/579 reads (22%) | catalogued as rs760879749, COSV54507117; called by muse, mutect2, varscan2
- IGFN1 | c.1241+1090C>T | Intron (SNP) | VAF 45/407 reads (11%) | called by muse, mutect2, varscan2
- IQSEC2 | c.2460-26G>A | Intron (SNP) | VAF 54/450 reads (12%) | catalogued as rs782012055; called by muse, mutect2, varscan2
- JPH3 | c.2167-942G>A | Intron (SNP) | VAF 48/443 reads (11%) | catalogued as rs767820964; called by muse, mutect2, varscan2
- KDR | c.-7G>A | 5'UTR (SNP) | VAF 62/824 reads (8%) | catalogued as rs776812966; called by muse, mutect2
- KIF1B | c.2115+6064C>T | Intron (SNP) | VAF 77/818 reads (9%) | catalogued as rs780600214; called by muse, mutect2
- LCN1 | c.*105C>T | 3'UTR (SNP) | VAF 10/214 reads (5%) | called by muse, mutect2
- LIG3 | c.2796+209C>T | Intron (SNP) | VAF 42/498 reads (8%) | catalogued as rs753303003; called by muse, mutect2
- LTBP3 | c.2597-15A>G | Intron (SNP) | VAF 83/779 reads (11%) | called by muse, mutect2, varscan2
- MED13L | c.4114+49A>G | Intron (SNP) | VAF 25/117 reads (21%) | called by muse, mutect2, varscan2
- MED27 | c.*8G>A | 3'UTR (SNP) | VAF 12/82 reads (15%) | catalogued as rs749935297; called by muse, mutect2, varscan2
- MGST3 | c.*17A>T | 3'UTR (SNP) | VAF 75/556 reads (13%) | called by muse, mutect2, varscan2
- MICALL2 | c.2476+14G>A | Intron (SNP) | VAF 24/387 reads (6%) | catalogued as rs1458516012; called by muse, mutect2
- MPHOSPH8 | c.2458-309G>T | Intron (SNP) | VAF 11/355 reads (3%) | called by muse, mutect2
- NRG1 | chr8:31639372 T>C | 5'Flank (SNP) | VAF 69/638 reads (11%) | called by muse, varscan2
- OVCH1-AS1 | n.432C>T | RNA (SNP) | VAF 63/711 reads (9%) | called by muse, mutect2
- POMGNT1 | c.1605-45T>C | Intron (SNP) | VAF 57/447 reads (13%) | called by muse, mutect2, varscan2
- PTGES2 | chr9:128129127 C>T | 5'Flank (SNP) | VAF 64/667 reads (10%) | called by muse, mutect2
- RAP1GAP | c.-148-1926T>C | Intron (SNP) | VAF 10/127 reads (8%) | catalogued as rs1268143917; called by muse, mutect2
- RGS12 | c.3411+41C>T | Intron (SNP) | VAF 26/213 reads (12%) | catalogued as rs766043248, COSV58748813; called by muse, mutect2, varscan2
- RNY4P30 | chr13:49891263 C>T | 5'Flank (SNP) | VAF 80/817 reads (10%) | called by muse, mutect2
- RPL26P30 | n.719C>T | RNA (SNP) | VAF 68/810 reads (8%) | catalogued as rs767015283; called by muse, mutect2
- RPS4XP21 | n.403A>G | RNA (SNP) | VAF 48/379 reads (13%) | called by muse, mutect2, varscan2
- SACS | c.*673G>A | 3'UTR (SNP) | VAF 19/248 reads (8%) | called by muse, mutect2
- SCN4B | c.*3078T>G | 3'UTR (SNP) | VAF 26/213 reads (12%) | called by muse, mutect2, varscan2
- SGCA | c.983+1151G>A | Intron (SNP) | VAF 103/687 reads (15%) | called by muse, mutect2, varscan2
- SIGMAR1 | c.*3A>G | 3'UTR (SNP) | VAF 78/1120 reads (7%) | called by muse, mutect2
- SSPOP | n.7540C>A | RNA (SNP) | VAF 26/358 reads (7%) | called by muse, mutect2
- TPSD1 | chr16:1262917 A>G | 3'Flank (SNP) | VAF 60/616 reads (10%) | called by muse, mutect2
- TRAPPC9 | chr8:140458550 C>T | 5'Flank (SNP) | VAF 70/584 reads (12%) | called by muse, mutect2, varscan2
- UNC13D | c.*49G>A | 3'UTR (SNP) | VAF 39/361 reads (11%) | called by muse, mutect2, varscan2
- VEGFB | c.*65G>A | 3'UTR (SNP) | VAF 39/444 reads (9%) | called by muse, mutect2
- ZNF497 | c.-111-587C>A | Intron (SNP) | VAF 76/567 reads (13%) | called by muse, mutect2, varscan2
- ZNF7 | c.247+555C>A | Intron (SNP) | VAF 36/369 reads (10%) | called by muse, mutect2, varscan2
